Somatic mutation profile of tumor specimen TCGA-G4-6307-01A (aliquot TCGA-G4-6307-01A-11D-1719-10) from TCGA case TCGA-G4-6307, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 37.4 years (13,648 days).
Specimen TCGA-G4-6307-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26461474-8e75-4642-adf8-3e6fe930e747.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6307-10A (Blood Derived Normal), aliquot TCGA-G4-6307-10A-01D-1720-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a9422c3-ce8e-4833-b684-c243255f271b

The open-access MAF lists 79 somatic variants for this specimen: 59 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 19, Nonsense Mutation 3, Splice Region 2, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 73/151 reads (48%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 91/118 reads (77%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs1567548929, COSV52662086, COSV52675732, COSV52773165, COSV52962390; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADCY1 | c.1841T>G p.V614G | Missense Mutation (SNP) | VAF 15/375 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.063); catalogued as COSV99811567; called by muse, mutect2
- CAD | c.4290C>G p.I1430M | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV99254677; called by muse, mutect2
- CAPN7 | c.2008C>T p.R670W | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53777705; called by muse, mutect2, varscan2
- CCDC7 | c.3687G>A p.Q1229= | Splice Region (SNP) | VAF 70/182 reads (38%) | catalogued as COSV56540410; called by muse, mutect2, varscan2
- CCM2L | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 152/282 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769382467, COSV52949977; called by muse, mutect2, varscan2
- CCNT1 | c.1993C>A p.H665N | Missense Mutation (SNP) | VAF 77/342 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99980619; called by muse, mutect2, varscan2
- CFAP77 | c.430C>A p.Q144K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.203); catalogued as COSV58009773; called by muse, mutect2, varscan2
- CLSTN2 | c.1438G>T p.V480L | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV71720093; called by muse, mutect2, varscan2
- CSMD2 | c.9080A>G p.D3027G | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs746637583, COSV53901497; called by muse, mutect2, varscan2
- CSMD2 | c.9079G>T p.D3027Y | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53901518; called by muse, mutect2, varscan2
- DCDC1 | c.5264G>C p.R1755T (on ENST00000597505 / NM_001367979.1; = p.R862T on NM_020869.3) | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100360385; called by muse, mutect2, varscan2
- DDX60L | c.2969C>T p.T990M | Missense Mutation (SNP) | VAF 161/414 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369510208, COSV52714774; called by muse, mutect2, varscan2
- DGKB | c.916G>T p.D306Y | Missense Mutation (SNP) | VAF 21/223 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV99337681; called by muse, mutect2, varscan2
- DMD | c.4011T>A p.D1337E | Missense Mutation (SNP) | VAF 57/286 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63747594; called by muse, mutect2, varscan2
- DNHD1 | c.11450G>A p.R3817Q | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs370710063, COSV99599207; called by muse, mutect2, varscan2
- DOCK3 | c.1978G>A p.G660S | Missense Mutation (SNP) | VAF 142/337 reads (42%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.969); catalogued as rs1333910032, COSV56514811; called by muse, mutect2, varscan2
- DSCAML1 | c.3033C>A p.D1011E (on ENST00000321322; = p.D951E on NM_020693.4) | Missense Mutation (SNP) | VAF 50/298 reads (17%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.81); catalogued as COSV100355218; called by muse, mutect2, varscan2
- DZIP1L | c.2250G>T p.E750D | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.468); catalogued as COSV59520190; called by muse, mutect2, varscan2
- ELOA2 | c.250C>G p.R84G | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs199546236, COSV55296461; called by muse, mutect2, varscan2
- FAM47B | c.1109C>A p.T370K | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.98); PolyPhen benign (0.005); catalogued as COSV61453294; called by muse, mutect2, varscan2
- FBLN1 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751912120, COSV53044334; called by muse, mutect2, varscan2
- FCER1A | c.188A>C p.K63T | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.031); catalogued as COSV100929251; called by muse, mutect2
- GPC4 | c.13G>A p.G5S | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV63697606; called by muse, mutect2, varscan2
- IGSF11 | c.724C>G p.L242V (on ENST00000393775 / NM_001015887.3; = p.L241V on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/276 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as COSV61168300; called by muse, mutect2, varscan2
- KCNQ5 | c.2078C>T p.T693M | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs777062053, COSV59649876; called by muse, mutect2, varscan2
- LRGUK | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 37/91 reads (41%) | catalogued as rs912239674, COSV53646219; called by muse, mutect2, varscan2
- MARK4 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV53463010; called by muse, varscan2
- MED14 | c.1151A>T p.K384I | Missense Mutation (SNP) | VAF 143/662 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV61356571; called by muse, mutect2, varscan2
- MUC16 | c.19523C>A p.T6508N | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.136); catalogued as rs183160657, COSV67459067; called by muse, mutect2, varscan2
- OR2W1 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 102/195 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs745574396, COSV65851508; called by muse, mutect2, varscan2
- OR4D9 | c.164T>G p.L55R | Missense Mutation (SNP) | VAF 30/428 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61434454, COSV61435629; called by muse, mutect2
- P2RY8 | c.118G>T p.G40C | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.768); catalogued as COSV67177095; called by muse, mutect2, varscan2
- PAX5 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 73/337 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as rs1313118042, COSV63905600; called by muse, mutect2, varscan2
- PCNX4 | c.193G>A p.G65S | Missense Mutation (SNP) | VAF 131/255 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100470070; called by muse, mutect2, varscan2
- PHF24 | c.53G>C p.S18T | Missense Mutation (SNP) | VAF 23/221 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV54273945; called by muse, mutect2
- PLXNA2 | c.4189C>T p.R1397C | Missense Mutation (SNP) | VAF 103/182 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs771610537, COSV65439741; called by muse, mutect2, varscan2
- PPARG | c.1477C>T p.L493F (on ENST00000287820 / NM_015869.5; = p.L463F on NM_005037.7) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55141867; called by muse, mutect2
- RARG | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs141058411; called by muse, mutect2, varscan2
- RIMS2 | c.2962G>T p.V988F (on ENST00000666250 / NM_001348490.2; = p.V796F on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.732); catalogued as COSV51671251; called by muse, mutect2, varscan2
- SEMG2 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as COSV65647369; called by muse, mutect2
- SPON1 | c.2355C>G p.F785L | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.061); catalogued as COSV100115499; called by muse, mutect2, varscan2
- SPTBN1 | c.5438A>G p.D1813G | Missense Mutation (SNP) | VAF 110/146 reads (75%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.919); catalogued as COSV61687537; called by muse, mutect2, varscan2
- SPTBN4 | c.1510C>T p.R504W | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs761610779, COSV58945239, COSV58953378; called by muse, mutect2, varscan2
- STK32B | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745729733, COSV51481411; called by muse, mutect2, varscan2
- SVIL | c.1613C>T p.S538L | Missense Mutation (SNP) | VAF 78/250 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs140127802, COSV63442310; called by muse, mutect2, varscan2
- TADA3 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1163816818, COSV55027969; called by muse, mutect2, varscan2
- TENM4 | c.4627G>T p.A1543S | Missense Mutation (SNP) | VAF 85/204 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV53621207; called by muse, mutect2, varscan2
- TMCO6 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as COSV52799530; called by muse, mutect2, varscan2
- TTN | c.74985G>T p.K24995N (on ENST00000591111; = p.K17571N on NM_003319.4) | Missense Mutation (SNP) | VAF 56/255 reads (22%) | PolyPhen possibly damaging (0.856); catalogued as COSV100601022; called by muse, mutect2, varscan2
- UBR5 | c.5998C>G p.Q2000E | Missense Mutation (SNP) | VAF 76/949 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.184); catalogued as COSV99640053; called by muse, mutect2
- USP47 | c.2828G>A p.R943Q (on ENST00000399455 / NM_001372095.1; = p.R855Q on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.921); catalogued as rs1236508359, COSV100359323; called by muse, mutect2, varscan2
- VCAM1 | c.1954G>A p.A652T | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0.013); catalogued as rs200910233; called by muse, mutect2, varscan2
- ZBTB40 | c.3046C>T p.Q1016* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100988853; called by muse, varscan2
- ZNF134 | c.1114T>A p.F372I | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.812); catalogued as COSV68696251; called by muse, mutect2, varscan2
- IGHV3-53 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.393); called by muse, varscan2
- SPRTN | c.797_799dup p.L266dup | In Frame Ins (INS) | VAF 34/133 reads (26%) | called by mutect2, pindel, varscan2
- USP6NL | c.828T>C p.T276= | Splice Region (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- ATG9A | c.546A>G p.E182= | Silent (SNP) | VAF 23/30 reads (77%) | catalogued as COSV60132794; called by muse, mutect2, varscan2
- C2orf76 | c.327C>T p.F109= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV58346258; called by muse, mutect2, varscan2
- C8A | c.123G>T p.L41= | Silent (SNP) | VAF 43/151 reads (28%) | catalogued as COSV63483640; called by muse, mutect2, varscan2
- CACNA1F | c.4026C>T p.A1342= | Silent (SNP) | VAF 98/244 reads (40%) | catalogued as rs140353265, COSV100544542, COSV100544956; called by muse, varscan2
- CARD11 | c.978G>T p.L326= | Silent (SNP) | VAF 56/126 reads (44%) | catalogued as COSV67798364; called by muse, mutect2, varscan2
- CEACAM3 | c.279C>T p.A93= | Silent (SNP) | VAF 249/494 reads (50%) | catalogued as rs782466052, COSV55761292; called by muse, mutect2, varscan2
- DMD | c.3891C>T p.G1297= | Silent (SNP) | VAF 22/390 reads (6%) | catalogued as rs758317261, COSV63747600; called by muse, mutect2
- ELP3 | c.198T>A p.P66= | Silent (SNP) | VAF 73/95 reads (77%) | catalogued as COSV56458677; called by muse, mutect2, varscan2
- GPR152 | c.1032G>A p.P344= | Silent (SNP) | VAF 107/245 reads (44%) | catalogued as rs773420319, COSV56886051; called by muse, mutect2, varscan2
- LCTL | c.672C>T p.T224= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs529701551, COSV58421840; called by muse, mutect2, varscan2
- LPA | c.4566C>A p.T1522= | Silent (SNP) | VAF 50/179 reads (28%) | catalogued as COSV60300342; called by muse, mutect2, varscan2
- LRP1B | c.9450C>T p.C3150= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as rs756957154, COSV67206068; called by muse, mutect2, varscan2
- MAG | c.1554C>T p.G518= | Silent (SNP) | VAF 83/150 reads (55%) | catalogued as rs200430942, COSV62699711; called by muse, mutect2, varscan2
- MXRA5 | c.261C>T p.H87= | Silent (SNP) | VAF 90/228 reads (39%) | catalogued as rs767408774, COSV54231571; called by muse, varscan2
- MYO16 | c.519C>T p.S173= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV51787579; called by muse, mutect2, varscan2
- POLR3D | c.462C>A p.I154= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV100120016; called by muse, mutect2, varscan2
- RMC1 | c.1251C>T p.N417= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV52571431; called by muse, mutect2, varscan2
- UTP6 | c.24C>T p.R8= | Silent (SNP) | VAF 26/162 reads (16%) | catalogued as rs753530970, COSV99911848; called by muse, mutect2, varscan2
- ZNF75D | c.1386C>A p.S462= | Silent (SNP) | VAF 65/353 reads (18%) | catalogued as COSV66132624; called by muse, mutect2, varscan2
- TP73-AS1 | n.1557G>A | RNA (SNP) | VAF 51/84 reads (61%) | catalogued as rs370516330; called by muse, mutect2, varscan2
